Gene-level copy-number profile of tumor specimen C3N-03837-01 from CPTAC case C3N-03837, project CPTAC-3 (Lip — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Lip, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 54.1 years (19,778 days).
Specimen C3N-03837-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Lip; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ad3b3d51-e080-42e5-bb71-bce14e413196.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-03837-31 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,710 have no estimate.
https://portal.gdc.cancer.gov/files/1d035bbe-bf96-4144-b37b-abbff67b6602

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 2,900; copy number 1: 2,883; copy number 2: 52,753; copy number 3: 253; copy number 4: 47; copy number 5: 77.

Homozygous deletions (total copy number 0; autosomes only): 2,891 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–90,261,708, 1,347 genes (broad region; genes not listed).
- chr17:142,789–22,706,703, 912 genes (broad region; genes not listed).
- chr18:33,552,123–80,247,514, 632 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 77 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:86,649–1,012,245, 77 genes, copy number 5 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 37. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
